TCGA case TCGA-ER-A2NB — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Skin; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bda2f09a-82c4-40ec-90e8-0bf63916a5c7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 57 years; Vital status: Dead; Days to death: 857 days (2.3 years).

Diagnoses (5)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C44.5; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of trunk; Classification of tumor: primary; Age at diagnosis: 57.7 years (21,062 days); Days to diagnosis: 124 days; Prior treatment: No; Days to last follow up: 857 days (2.3 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: IV; Sites of involvement: Skin, Groin; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >4.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
3. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 57.3 years (20,938 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T4b; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
4. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Pelvic lymph nodes. Age at diagnosis: 58.6 years (21,399 days); Days to diagnosis: 461 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 470 days (1.3 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
5. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 3 of this record; Age at diagnosis: 58.6 years (21,399 days); Days to diagnosis: 461 days (1.3 years); Prior treatment: Yes.

Follow-up (3 entries)
- Day 461 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Pelvic lymph nodes; Days to progression: 461 days (1.3 years).
- Days to follow up: 486 days (1.3 years); Disease response: With Tumor.
- Days to follow up: 857 days (2.3 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 1.3.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-ER-A2NB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 180 mg.
  Slide TCGA-ER-A2NB-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 0.
- Sample TCGA-ER-A2NB-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-ER-A2NB-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Breslow thickness at diagnosis: 4.39; Radiation therapy to primary: No; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No.
- Sites of primary melanomas, Site: Submitted tumor site: Other  Specify; Site of primary tumor other: Anus.
- Prior systemic therapy types: History neoadjuvant treatment type: Immunotherapy/Vaccine.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: Patient received immunotherapy/vaccine for the TCGA tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 857 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 857 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 461 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-ER-A2NB-01A-12D-A194-01): tumor purity 0.29, ploidy 4.37, whole-genome doublings 2.
